Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-8470, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-8470-01A (Primary Tumor).

FINAL DIAGNOSIS:

Part 1: LYMPH NODE, LEFT PELVIC, EXCISION –

NO EVIDENCE OF CARCINOMA IN ONE LYMPH NODE (0/1).

Part 2: LYMPH NODES, RIGHT PELVIC, EXCISION –

NO EVIDENCE OF CARCINOMA IN THIRTEEN LYMPH NODES (0/13).

Part 3: LYMPH NODES, LEFT PELVIC, EXCISION –

NO EVIDENCE OF CARCINOMA IN SEVEN LYMPH NODES (0/7).

Part 4: PROSTATE AND SEMINAL VESICLES (66.88 GRAMS), PROSTATECTOMY –

- A. POORLY DIFFERENTIATED PROSTATE ADENOCARCINOMA, GLEASON SCORE 4 + 3 = 7.
- B. THE CARCINOMA INVOLVES BOTH LEFT AND RIGHT LOBES, AND INVOLVES LESS THAN 5% OF THE TOTAL PROSTATIC TISSUE EVALUATED.
- C. THE GREATEST NODULAR DIAMETER OF CARCINOMA IS 0.8 CM.
- D. THE CARCINOMA IS ORGAN CONFINED, WITH NO EXTRACAPSULAR EXTENSION IDENTIFIED.
- E. BILATERAL SEMINAL VESICLES ARE FREE OF CARCINOMA.
- F. PERINEURAL INVASION IS IDENTIFIED.
- G. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- H. HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN) IS IDENTIFIED.
- I. HISTOLOGIC GRADE: G3.
- J. TNM PATHOLOGIC STAGE: pT2c N0 MX.
- K. NON-NEOPLASTIC PROSTATE WITH EXTENSIVE, SEVERE CHRONIC AND GRANULOMATOUS PROSTATITIS.

Part 5: MASS, PERIRECTAL, BIOPSIES –

- A. NO EVIDENCE OF CARCINOMA.
- B. FIBROADIPOSE TISSUE WITH SEVERE CHRONIC AND GRANULOMATOUS INFLAMMATION.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA:	PSA value: 14.1
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	4
SECONDARY GLEASON GRADE:	3
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	60%
WEIGHT OF PROSTATE:	66.88gm
TUMOR SIZE:	Maximum dimension: 0.8 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	< 5% of specimen involved by invasive tumor
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	No
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
RESIDUAL TUMOR:	R0
LYMPH NODES EXAMINED:	21
LYMPH NODES POSITIVE:	0
EXTRANODAL EXTENSION:	No
T STAGE, PATHOLOGIC:	pT2c
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file 0011a9d0-20fb-4b65-9427-88b95580c37f (TCGA-EJ-8470.E53212BF-D686-4ACC-8859-00CBDDDD627C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).